Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WL, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WL-01A (Primary Tumor).

Neuropathology

Patient:

B-Day:

Patho-No.:

Commentary:

Histology and morphology correspond to anaplastic astrocytoma WHO grade III.

Diagnosis:

Anaplastic astrocytoma WHO grade III

ICD-O-3

Astrocytoma, grade III
9401/3

Site Brain, supratentorial
C71.0

QW 8/12/13

Untranslated full report is
housed at the BCR.

Source: NCI Genomic Data Commons file b4d6418a-f979-47d5-84e3-9711f974de33 (TCGA-S9-A6WL.55E391EF-4395-4ED7-8B56-DBDA1EB61FD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).